Somatic mutation profile of tumor specimen TCGA-R2-A69V-01A (aliquot TCGA-R2-A69V-01A-11D-A32I-09) from TCGA case TCGA-R2-A69V, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 42.4 years (15,479 days).
Specimen TCGA-R2-A69V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a30b256-2493-402b-b02f-bfa089414db2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R2-A69V-10A (Blood Derived Normal), aliquot TCGA-R2-A69V-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b2f4436-5bb8-4c0c-8652-ea932f313fd7

The open-access MAF lists 101 somatic variants for this specimen: 72 protein-altering or splice-affecting, 29 silent.
By variant classification: Missense Mutation 63, Silent 29, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD34A | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.364); catalogued as COSV60160784; called by muse, mutect2
- APCDD1L | c.860C>G p.S287W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV64486065; called by muse, mutect2, varscan2
- ARSL | c.1398G>C p.W466C | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101140640; called by muse, mutect2
- ATP6V1B1 | c.699G>C p.E233D | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV99314273; called by muse, mutect2
- BMS1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 23/319 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as COSV100996743; called by muse, mutect2
- CACNA1B | c.594G>T p.R198S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53122516; called by muse, mutect2, varscan2
- CACNA1I | c.4983C>G p.F1661L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100360776; called by muse, mutect2
- CARD11 | c.708G>C p.L236F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67798479; called by muse, mutect2, varscan2
- CASP8 | c.717C>G p.I239M (on ENST00000432109 / NM_033355.3; = p.I256M on NM_001228.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV51860909; called by muse, mutect2
- CD1E | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as rs775938225, COSV63770003, COSV63770928; called by muse, varscan2
- CFH | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.244); catalogued as rs145347741, CM100538; called by muse, mutect2
- CHM | c.1010T>C p.V337A | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63301320; called by muse, mutect2, varscan2
- CILP2 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs541483234, COSV52274211; called by muse, mutect2, varscan2
- COL16A1 | c.3071G>C p.G1024A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54704157; called by muse, mutect2, varscan2
- CTSV | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV52344654; called by muse, mutect2, varscan2
- DDX19A | c.1376-1G>C p.X459_splice | Splice Site (SNP) | VAF 7/112 reads (6%) | catalogued as COSV100156341; called by muse, mutect2
- DHTKD1 | c.1676G>C p.R559T | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53808048, COSV99536631; called by muse, mutect2
- DHX34 | c.2616G>C p.M872I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV60895122; called by muse, mutect2, varscan2
- DLG5 | c.4468G>C p.A1490P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64947636; called by muse, mutect2, varscan2
- DOCK1 | c.4997G>C p.G1666A | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.312); catalogued as COSV54737025; called by muse, mutect2
- EML3 | c.972G>C p.Q324H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53882070; called by muse, mutect2, varscan2
- FMNL1 | c.2779G>C p.E927Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58956460; called by muse, mutect2
- GAA | c.1864G>T p.E622* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV56408096; called by muse, mutect2, varscan2
- GCKR | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); catalogued as COSV53107506, COSV99268815; called by muse, mutect2
- GFPT2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs772616408, COSV53807896; called by muse, mutect2, varscan2
- GRM6 | c.721+2T>G p.X241_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as rs759081308, COSV51439237; called by muse, mutect2, varscan2
- HECTD2 | c.1313G>C p.R438T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs753142699, COSV99978729; called by muse, mutect2, varscan2
- HECW1 | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV101223918, COSV67826964; called by muse, mutect2
- IFNA10 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53330910; called by muse, mutect2, varscan2
- INHBB | c.983A>G p.Y328C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54677732; called by muse, mutect2, varscan2
- IPO11 | c.1439C>G p.P480R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV57575293; called by muse, mutect2, varscan2
- IPPK | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.621); catalogued as COSV55333526; called by muse, mutect2, varscan2
- KRTAP19-3 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen probably damaging (0.978); catalogued as COSV100477597, COSV61854590; called by muse, mutect2
- L1CAM | c.1553C>G p.T518S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62827779; called by muse, mutect2, varscan2
- LMTK3 | c.4132G>A p.E1378K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as COSV54311466; called by muse, mutect2, varscan2
- LRRK1 | c.5787C>G p.I1929M | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as COSV99441140, COSV99443350; called by muse, mutect2, varscan2
- MEGF11 | c.1309T>C p.C437R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56549036, COSV56559989; called by muse, mutect2, varscan2
- MTPAP | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV53932469; called by muse, mutect2, varscan2
- NCOR1 | c.2750C>G p.S917* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV99250644; called by muse, mutect2
- NES | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100957917; called by muse, mutect2
- NKX2-8 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.089); catalogued as COSV51874071; called by muse, mutect2
- OR5M8 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV59116491; called by muse, mutect2
- OS9 | c.211T>A p.Y71N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV57782639; called by muse, mutect2, varscan2
- PADI1 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs777501866, COSV64938240; called by muse, mutect2, varscan2
- PMP2 | c.210A>T p.E70D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV56266935; called by muse, mutect2, varscan2
- PRKAG2 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as COSV55227476, COSV99835074; called by muse, mutect2
- PSMC1 | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as COSV54320613, COSV54322253; called by muse, mutect2, varscan2
- PTCHD4 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1313239771, COSV59782146; called by muse, mutect2, varscan2
- RADX | c.1277C>A p.P426Q | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100998863; called by muse, mutect2
- RBM10 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782214369, COSV61308161; called by muse, mutect2, varscan2
- RRN3 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV99548908; called by muse, mutect2, varscan2
- SEPTIN4 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV58727351, COSV58727648; called by mutect2, varscan2
- SLC1A7 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 11/133 reads (8%) | catalogued as COSV101019681; called by muse, mutect2
- SLC43A3 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV61450220; called by muse, mutect2, varscan2
- SLC44A2 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs752432975, COSV59836300; called by mutect2, varscan2
- SPNS2 | c.1095C>G p.I365M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV100223811, COSV61230098; called by muse, mutect2, varscan2
- ST8SIA2 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | PolyPhen benign (0.003); catalogued as COSV99184466; called by muse, mutect2
- SULT1A1 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV100131924, COSV59087033; called by muse, mutect2
- SYNE3 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV62079085; called by muse, mutect2
- SYT13 | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.197); catalogued as COSV50073204; called by muse, mutect2, varscan2
- TMEM120B | c.863C>G p.T288R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57362987; called by muse, mutect2, varscan2
- TP63 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53203584; called by muse, mutect2, varscan2
- TXNDC5 | c.593A>C p.N198T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as rs1409314462, COSV65730291, COSV65730780; called by muse, mutect2, varscan2
- UGT2B10 | c.1054C>A p.L352M | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV55319867; called by muse, mutect2, varscan2
- VEZT | c.800G>C p.R267T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV54138028; called by muse, mutect2, varscan2
- XKRX | c.1214T>G p.L405W | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60707802; called by muse, mutect2
- ZNF283 | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61031038; called by mutect2, varscan2
- ZNF783 | c.523A>G p.N175D | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65185229; called by muse, mutect2, varscan2
- CFAP126 | c.319A>C p.N107H | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ELOA | c.634_646del p.P212Tfs*50 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- TRAV16 | c.47-12_52del p.X16_splice | Splice Site (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- TRAV20 | c.216T>G p.Y72* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- ACSF2 | c.417C>G p.L139= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV51972030; called by muse, mutect2, varscan2
- ACTL9 | c.63C>G p.G21= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV61005527; called by muse, mutect2, varscan2
- ADCY4 | c.2148C>T p.I716= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs780808869, COSV60253649, COSV60256897; called by muse, mutect2, varscan2
- CCKBR | c.756C>T p.D252= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs747685589, COSV58100637; called by muse, mutect2, varscan2
- GSN | c.978G>C p.L326= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV57996810; called by muse, varscan2
- IARS2 | c.1344G>A p.Q448= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV100228415; called by muse, mutect2
- JAKMIP1 | c.2106C>T p.F702= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV68952177; called by muse, mutect2, varscan2
- LATS1 | c.2844T>G p.P948= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV53589539; called by muse, mutect2
- LHFPL5 | c.81G>C p.V27= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV64177595; called by muse, mutect2, varscan2
- LRBA | c.8265C>G p.V2755= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100841832; called by muse, mutect2, varscan2
- MAFB | c.219C>T p.F73= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100965057; called by muse, mutect2
- NLRX1 | c.1422G>C p.L474= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs768901206, COSV52703520; called by muse, mutect2, varscan2
- PLXNA1 | c.1809C>T p.F603= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV52525050; called by muse, mutect2, varscan2
- PNKP | c.1200C>T p.G400= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1188834887, COSV99681856; called by muse, mutect2
- PRR16 | c.57G>T p.P19= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV65398020; called by muse, mutect2
- RAD50 | c.123A>G p.G41= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV54750386; called by muse, mutect2, varscan2
- RBMX2 | c.285C>T p.D95= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV59728702; called by muse, mutect2, varscan2
- RNF126 | c.306T>G p.A102= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52777816; called by mutect2, varscan2
- S1PR1 | c.975C>T p.I325= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV59513044; called by muse, mutect2
- SCGN | c.612A>G p.K204= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV58545195; called by muse, mutect2, varscan2
- SIT1 | c.492C>G p.P164= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV52399675, COSV52399805; called by muse, mutect2, varscan2
- SLC26A4 | c.580C>T p.L194= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV55915829; called by muse, mutect2, varscan2
- SLC2A6 | c.129C>T p.F43= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as rs372451832, COSV64141815; called by muse, mutect2, varscan2
- TAOK3 | c.183G>A p.Q61= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- TBP | c.894C>G p.P298= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100027397; called by muse, mutect2, varscan2
- TUT4 | c.1287G>C p.L429= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV99932527; called by muse, mutect2
- UBR1 | c.1782A>G p.E594= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV51928751; called by muse, mutect2, varscan2
- XKR9 | c.813T>A p.L271= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV68772821; called by muse, mutect2, varscan2
- ZNF517 | c.579C>G p.L193= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100743703; called by muse, mutect2
